Somatic mutation profile of tumor specimen TCGA-CU-A3YL-01A (aliquot TCGA-CU-A3YL-01A-11D-A22Z-08) from TCGA case TCGA-CU-A3YL, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 67.1 years (24,524 days).
Specimen TCGA-CU-A3YL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ee08b183-ac09-45e6-b53e-a19273f06a7e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CU-A3YL-10A (Blood Derived Normal), aliquot TCGA-CU-A3YL-10A-01D-A22Z-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ec5dfc03-b342-429c-8d8b-efb8ca30cab5

The open-access MAF lists 252 somatic variants for this specimen: 201 protein-altering or splice-affecting, 45 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 172, Silent 45, Nonsense Mutation 13, Frame Shift Del 7, Frame Shift Ins 5, Splice Site 3, RNA 2, Intron 2, Splice Region 1, 3'UTR 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CREBBP | c.4303G>C p.D1435H | Missense Mutation (SNP) | VAF 5/16 reads (31%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52114189, COSV52125802, COSV52127728; called by muse, mutect2
- ERBB2 | c.2264T>C p.L755S | Missense Mutation (SNP) | VAF 17/41 reads (41%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913470, COSV54062780, COSV54064269; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ACAN | c.1756C>T p.L586F | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated (0.19); PolyPhen benign (0.215); catalogued as rs761732451, COSV61371275; called by muse, mutect2, varscan2
- AKAP11 | c.1997C>T p.S666L | Missense Mutation (SNP) | VAF 30/111 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50299722; called by muse, mutect2, varscan2
- ANK3 | c.9448G>C p.D3150H | Missense Mutation (SNP) | VAF 29/105 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.972); catalogued as COSV55086878; called by muse, mutect2, varscan2
- ANKRD26 | c.2069C>T p.S690L | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.865); catalogued as COSV101062894, COSV65778968; called by muse, mutect2, varscan2
- ARHGAP25 | c.1038G>C p.M346I (on ENST00000409202 / NM_001007231.3; = p.M338I on NM_014882.3) | Missense Mutation (SNP) | VAF 58/156 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV54910432; called by muse, mutect2, varscan2
- ARID1A | c.1519C>T p.Q507* | Nonsense Mutation (SNP) | VAF 6/200 reads (3%) | catalogued as COSV61372392, COSV61377138; called by muse, mutect2
- ARL3 | c.224G>C p.R75T | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV53301474; called by muse, mutect2
- ARL6IP6 | c.358C>G p.L120V | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.178); catalogued as COSV58444803; called by muse, mutect2, varscan2
- ARVCF | c.2605G>A p.D869N | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1261527417, COSV52891237; called by muse, mutect2
- ATAD2 | c.1366A>T p.K456* | Nonsense Mutation (SNP) | VAF 27/70 reads (39%) | catalogued as COSV54879794; called by muse, mutect2, varscan2
- AXDND1 | c.1435G>C p.E479Q | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as COSV100858256, COSV62650481; called by muse, mutect2, varscan2
- BASP1 | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.736); catalogued as COSV59474394; called by muse, mutect2, varscan2
- BTLA | c.536G>C p.R179T | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.382); catalogued as COSV57941095; called by muse, mutect2, varscan2
- BUB1B | c.659C>G p.S220C | Missense Mutation (SNP) | VAF 27/55 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); catalogued as COSV55017727; called by muse, mutect2, varscan2
- C3orf20 | c.935G>A p.R312Q | Missense Mutation (SNP) | VAF 28/106 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.343); catalogued as rs768861528, COSV53782331, COSV99513234; called by muse, mutect2, varscan2
- CCDC28A | c.340G>A p.E114K | Missense Mutation (SNP) | VAF 35/78 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); catalogued as rs760669204, COSV60425229; called by muse, mutect2, varscan2
- CDC42BPB | c.3197C>A p.S1066Y | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.793); catalogued as COSV63477303; called by muse, mutect2, varscan2
- CDK11A | c.1522G>A p.E508K (on ENST00000378633 / NM_001313896.2; = p.E505K on NM_024011.4) | Missense Mutation (SNP) | VAF 9/14 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV52308759; called by muse, mutect2, varscan2
- CDK11A | c.230G>C p.G77A | Missense Mutation (SNP) | VAF 43/69 reads (62%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.793); catalogued as COSV62267183; called by muse, mutect2, varscan2
- CELF2 | c.1261G>C p.E421Q (on ENST00000416382 / NM_001025077.3; = p.E434Q on NM_006561.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.035); catalogued as COSV59980950, COSV59984201; called by muse, mutect2, varscan2
- CHD4 | c.3184-1G>A p.X1062_splice (on ENST00000357008 / NM_001363606.2; = p.X1075_splice on NM_001273.5) | Splice Site (SNP) | VAF 72/168 reads (43%) | catalogued as COSV58912877; called by muse, mutect2, varscan2
- CLGN | c.1784G>A p.G595E | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.762); catalogued as rs767973851, COSV57776932; called by muse, mutect2, varscan2
- CNTNAP2 | c.631G>T p.V211F | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.741); catalogued as COSV62271176; called by muse, mutect2, varscan2
- COL18A1 | c.1450G>A p.V484I (on ENST00000359759 / NM_130444.3; = p.V249I on NM_030582.4) | Missense Mutation (SNP) | VAF 34/88 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.048); catalogued as rs1405984023, COSV62708251; called by muse, mutect2, varscan2
- CPLANE1 | c.7983C>G p.F2661L | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as COSV57077042; called by muse, mutect2, varscan2
- CUL1 | c.1258G>A p.E420K | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57393250; called by muse, mutect2, varscan2
- DCDC1 | c.508C>G p.Q170E | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.273); catalogued as COSV60838605, COSV60862353; called by muse, mutect2, varscan2
- DENND5B | c.1263G>C p.K421N | Missense Mutation (SNP) | VAF 34/88 reads (39%) | SIFT tolerated (0.23); PolyPhen benign (0.196); catalogued as COSV60909673; called by muse, mutect2, varscan2
- DNAL4 | c.13G>C p.E5Q | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.143); catalogued as COSV53309913; called by muse, varscan2
- DPP3 | c.847G>A p.E283K | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated (0.56); PolyPhen benign (0.007); catalogued as COSV64758311; called by muse, mutect2, varscan2
- DSP | c.2623G>C p.D875H | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs200338012, COSV65796887; called by muse, mutect2, varscan2
- DYNC2I1 | c.160G>A p.E54K | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0.05); PolyPhen benign (0.358); catalogued as COSV68107769; called by muse, mutect2, varscan2
- EFEMP1 | c.448C>T p.P150S | Missense Mutation (SNP) | VAF 48/106 reads (45%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV62618288; called by muse, mutect2, varscan2
- ELF3 | c.18del p.I7Lfs*36 | Frame Shift Del (DEL) | VAF 18/47 reads (38%) | catalogued as COSV62840902; called by mutect2, pindel, varscan2
- EPM2AIP1 | c.1408G>C p.E470Q | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.506); catalogued as COSV51625713, COSV99212665; called by muse, mutect2, varscan2
- FAM118A | c.723G>T p.Q241H | Missense Mutation (SNP) | VAF 42/112 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.897); catalogued as rs1032241093, COSV53420002; called by muse, mutect2, varscan2
- FAT1 | c.7870del p.D2624Mfs*19 | Frame Shift Del (DEL) | VAF 10/42 reads (24%) | catalogued as COSV71675209, COSV71676326; called by mutect2, pindel, varscan2
- FBN2 | c.7267G>C p.E2423Q | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.261); catalogued as rs1193159709, COSV52550750; called by muse, mutect2, varscan2
- FBXO10 | c.1237G>C p.E413Q | Missense Mutation (SNP) | VAF 10/11 reads (91%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV52836302; called by muse, mutect2, varscan2
- FERMT3 | c.550C>T p.H184Y | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT tolerated (1); PolyPhen benign (0.297); catalogued as COSV54184482; called by muse, mutect2, varscan2
- FKBP15 | c.3469C>T p.H1157Y | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as COSV53040731; called by muse, mutect2, varscan2
- FLT4 | c.3289G>A p.V1097M | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs781402372, COSV56100743; called by muse, mutect2, varscan2
- FUZ | c.1088G>C p.R363T | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.525); catalogued as COSV58243322; called by muse, mutect2, varscan2
- GBP1 | c.8C>T p.S3L | Missense Mutation (SNP) | VAF 29/92 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV65084709; called by muse, mutect2, varscan2
- GIMAP7 | c.607G>C p.D203H | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.139); catalogued as COSV57961089; called by muse, mutect2, varscan2
- GOLGB1 | c.8920A>G p.I2974V | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.031); catalogued as COSV61463332; called by muse, mutect2, varscan2
- GPR107 | c.1267_1270del p.I423Dfs*25 (on ENST00000372406 / NM_001136557.2; = p.I423Dfs*17 on NM_020960.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 15/25 reads (60%) | catalogued as rs1388982689; called by mutect2, pindel, varscan2
- GRB14 | c.343G>A p.E115K | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.981); catalogued as COSV55744618; called by muse, mutect2, varscan2
- GRIK2 | c.2713G>C p.E905Q | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.104); catalogued as COSV59780376; called by muse, mutect2, varscan2
- GRK2 | c.1716C>G p.F572L | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0.05); PolyPhen benign (0.067); catalogued as COSV57755224; called by muse, mutect2, varscan2
- H1-2 | c.549G>C p.K183N | Missense Mutation (SNP) | VAF 30/84 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV59189495, COSV59192261; called by muse, mutect2, varscan2
- HIVEP3 | c.5248G>A p.G1750S | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1218302973, COSV56025664; called by muse, mutect2, varscan2
- HTRA3 | c.574G>A p.V192M | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs560803093, COSV56473873; called by muse, mutect2, varscan2
- INTS2 | c.3154G>C p.E1052Q | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.969); catalogued as COSV52157399; called by muse, mutect2, varscan2
- KAT6A | c.5221G>T p.A1741S | Missense Mutation (SNP) | VAF 34/112 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0.341); catalogued as COSV55912856; called by muse, mutect2, varscan2
- KCND1 | c.899T>C p.F300S | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54416446; called by muse, mutect2, varscan2
- KCNJ1 | c.519C>G p.F173L | Missense Mutation (SNP) | VAF 38/90 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60662375, COSV60663262; called by muse, mutect2, varscan2
- KCNK10 | c.532G>A p.E178K | Missense Mutation (SNP) | VAF 26/93 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.124); catalogued as COSV56653484, COSV56654278; called by muse, mutect2, varscan2
- KIAA0319L | c.2269G>A p.E757K | Missense Mutation (SNP) | VAF 36/81 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV57851957; called by muse, mutect2, varscan2
- KIAA1210 | c.1312G>C p.E438Q | Missense Mutation (SNP) | VAF 32/37 reads (86%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.844); catalogued as COSV68180841; called by muse, mutect2, varscan2
- KMT2D | c.6932C>T p.S2311F | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.916); catalogued as COSV56494707; called by muse, mutect2, varscan2
- KMT2D | c.6019G>T p.E2007* | Nonsense Mutation (SNP) | VAF 3/14 reads (21%) | catalogued as COSV56433074, COSV99977188; called by muse, mutect2
- KRI1 | c.951C>G p.I317M | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT tolerated (0.13); PolyPhen probably damaging (1); catalogued as COSV57264811, COSV57266112; called by muse, mutect2, varscan2
- LCN15 | c.26del p.I9Tfs*2 | Frame Shift Del (DEL) | VAF 7/17 reads (41%) | catalogued as COSV60211791; called by mutect2, pindel, varscan2
- LHCGR | c.1720C>T p.L574F | Missense Mutation (SNP) | VAF 42/109 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54304490; called by muse, mutect2, varscan2
- LHX4 | c.898C>G p.Q300E | Missense Mutation (SNP) | VAF 41/124 reads (33%) | SIFT tolerated (0.51); PolyPhen benign (0.028); catalogued as COSV55378658; called by muse, mutect2, varscan2
- LIPE | c.1172C>A p.S391Y | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.812); catalogued as COSV54926179; called by muse, mutect2, varscan2
- LRBA | c.3257C>T p.S1086L | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.003); catalogued as rs1378928452, COSV63966989; called by muse, mutect2, varscan2
- LRP1 | c.1523C>G p.S508C | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as COSV54529225; called by muse, mutect2, varscan2
- MAP3K8 | c.127G>C p.E43Q | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.11); catalogued as COSV53922181; called by muse, mutect2, varscan2
- MAP4K1 | c.505C>T p.R169C | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as rs1309678682, COSV67709791; called by muse, mutect2, varscan2
- MARK2 | c.389A>T p.E130V | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59290099; called by muse, mutect2, varscan2
- MECOM | c.280A>C p.M94L (on ENST00000468789 / NM_001105078.4; = p.M282L on NM_004991.4) | Missense Mutation (SNP) | VAF 37/65 reads (57%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as COSV52977302; called by muse, mutect2, varscan2
- METTL14 | c.375C>A p.D125E | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV66311496; called by muse, mutect2, varscan2
- MFSD11 | c.226C>T p.Q76* | Nonsense Mutation (SNP) | VAF 60/164 reads (37%) | catalogued as COSV60628399; called by muse, mutect2, varscan2
- MIDN | c.842C>G p.S281* | Nonsense Mutation (SNP) | VAF 21/89 reads (24%) | catalogued as rs778805669; called by muse, mutect2, varscan2
- MIPOL1 | c.950C>G p.S317C | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.639); catalogued as COSV59384669; called by muse, mutect2
- MTUS1 | c.3385-1G>A p.X1129_splice (on ENST00000262102 / NM_001363061.1; = p.X295_splice on NM_020749.4) | Splice Site (SNP) | VAF 34/51 reads (67%) | catalogued as rs1284993029, COSV50604240; called by muse, mutect2, varscan2
- MXRA5 | c.5003C>G p.S1668* | Nonsense Mutation (SNP) | VAF 163/199 reads (82%) | catalogued as COSV54239856; called by muse, mutect2, varscan2
- MYH7 | c.5314G>C p.E1772Q | Missense Mutation (SNP) | VAF 25/99 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62523303, COSV62525073; called by muse, mutect2, varscan2
- NCKAP1 | c.2712G>C p.L904F | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); catalogued as COSV62941813; called by muse, mutect2, varscan2
- NCOR1 | c.6350C>G p.S2117* | Nonsense Mutation (SNP) | VAF 35/102 reads (34%) | catalogued as COSV51980318, COSV99246870; called by muse, varscan2
- NCOR1 | c.6293C>T p.S2098L | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV52000482; called by muse, varscan2
- NCOR1 | c.6001C>G p.Q2001E | Missense Mutation (SNP) | VAF 29/92 reads (32%) | SIFT tolerated (0.23); PolyPhen benign (0.014); catalogued as COSV52000501; called by muse, mutect2, varscan2
- NEGR1 | c.350C>T p.T117M | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60879626; called by muse, mutect2, varscan2
- NEMP1 | c.96G>C p.L32F | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.916); catalogued as COSV55665027; called by muse, mutect2, varscan2
- NFATC4 | c.1742C>T p.S581L | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.649); catalogued as COSV51613529; called by muse, mutect2, varscan2
- NGF | c.257G>A p.R86H | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs200629339, COSV101049731; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NLK | c.1282G>C p.D428H | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.868); catalogued as COSV69411271; called by muse, mutect2, varscan2
- NOTCH2 | c.5527G>C p.D1843H | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV56689773; called by muse, mutect2, varscan2
- NOTCH3 | c.5068C>T p.H1690Y | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.296); catalogued as COSV54654144; called by muse, mutect2, varscan2
- NTRK2 | c.1408G>A p.V470I (on ENST00000323115 / NM_001369534.1; = p.V486I on NM_006180.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs201028496, COSV52876065; called by muse, mutect2
- NUP188 | c.4993C>G p.Q1665E | Missense Mutation (SNP) | VAF 36/124 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV65330871, COSV65332089; called by muse, mutect2, varscan2
- NWD1 | c.2941-1G>C p.X981_splice | Splice Site (SNP) | VAF 33/107 reads (31%) | catalogued as COSV60353740; called by muse, mutect2, varscan2
- OCLN | c.611C>G p.S204C | Missense Mutation (SNP) | VAF 64/184 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV62286214; called by muse, mutect2, varscan2
- OR2A4 | c.143T>A p.I48N | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.657); catalogued as COSV100199604; called by muse, varscan2
- OR2T3 | c.956del p.*319delext*? | Frame Shift Del (DEL) | VAF 33/221 reads (15%) | catalogued as COSV62083965; called by mutect2, pindel, varscan2
- OR5H2 | c.379C>T p.R127C | Missense Mutation (SNP) | VAF 32/134 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs770093101, COSV62350222, COSV62350448; called by muse, mutect2, varscan2
- PCDHB1 | c.2305C>G p.R769G | Missense Mutation (SNP) | VAF 31/100 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.32); catalogued as COSV60629496, COSV60633816; called by muse, mutect2, varscan2
- PCDHB6 | c.574G>C p.E192Q | Missense Mutation (SNP) | VAF 44/109 reads (40%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.208); catalogued as COSV50694084, COSV50742999; called by muse, mutect2, varscan2
- PCNX2 | c.2374C>G p.L792V | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT tolerated (0.14); PolyPhen benign (0.15); catalogued as COSV50941443; called by muse, mutect2, varscan2
- PDIA5 | c.881C>T p.S294F | Missense Mutation (SNP) | VAF 48/80 reads (60%) | SIFT deleterious (0.03); PolyPhen benign (0.389); catalogued as COSV60253265; called by muse, mutect2, varscan2
- PHACTR4 | c.1865G>C p.R622P (on ENST00000373839 / NM_001350159.2; = p.R632P on NM_023923.4) | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65785351; called by muse, mutect2, varscan2
- PHLPP2 | c.624G>C p.K208N | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.82); catalogued as COSV62427829; called by muse, mutect2
- PLCL1 | c.446C>T p.S149L | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs775400640, COSV70886362; called by muse, mutect2, varscan2
- PLEK | c.45G>C p.G15= | Splice Region (SNP) | VAF 9/35 reads (26%) | catalogued as COSV52253115; called by muse, mutect2, varscan2
- PLXNB2 | c.1085T>C p.F362S | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.526); catalogued as COSV63785070; called by muse, mutect2
- PNN | c.70G>A p.E24K | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.639); catalogued as COSV53768804; called by muse, mutect2, varscan2
- POLR2E | c.516G>T p.R172S | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV53125564; called by muse, mutect2, varscan2
- PPP1CB | c.387C>G p.I129M | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV56092325; called by muse, mutect2, varscan2
- PPP1R14C | c.343G>A p.D115N | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); catalogued as COSV63176860; called by muse, mutect2, varscan2
- PRKN | c.442G>T p.V148L | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.54); catalogued as rs1259302587, COSV58288037; called by muse, mutect2, varscan2
- PRMT7 | c.865G>C p.E289Q | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT tolerated (0.17); PolyPhen benign (0.103); catalogued as COSV59834291, COSV59836331; called by muse, mutect2, varscan2
- PRPF19 | c.119A>G p.D40G | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.999); catalogued as COSV57129610; called by muse, mutect2, varscan2
- PTGS2 | c.1768G>A p.D590N | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.006); catalogued as rs373482960; called by muse, mutect2, varscan2
- PURB | c.874G>A p.E292K | Missense Mutation (SNP) | VAF 27/91 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.956); catalogued as COSV67480655; called by muse, mutect2, varscan2
- PVR | c.773G>A p.G258D | Missense Mutation (SNP) | VAF 92/164 reads (56%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.53); catalogued as COSV51825158; called by muse, mutect2, varscan2
- RAB3GAP1 | c.2125G>A p.E709K | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.156); catalogued as COSV51490213; called by muse, mutect2, varscan2
- RAI1 | c.4523C>T p.S1508F | Missense Mutation (SNP) | VAF 29/35 reads (83%) | SIFT deleterious (0.01); PolyPhen benign (0.135); catalogued as rs376509042, COSV55400462; called by muse, mutect2, varscan2
- RAP2A | c.475G>A p.E159K | Missense Mutation (SNP) | VAF 29/118 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.625); catalogued as COSV55356462; called by muse, mutect2, varscan2
- RAPGEF4 | c.2482G>A p.V828I | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT tolerated (0.28); PolyPhen benign (0.031); catalogued as rs575529555, COSV51383834; called by muse, mutect2, varscan2
- RGL1 | c.2138C>T p.S713L (on ENST00000360851 / NM_001297672.2; = p.S748L on NM_015149.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.025); catalogued as COSV58998279; called by muse, mutect2, varscan2
- RNF213 | c.6424G>A p.E2142K | Missense Mutation (SNP) | VAF 82/209 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.335); catalogued as COSV60408769, COSV60411402; called by muse, mutect2, varscan2
- RPS4X | c.628G>A p.V210M | Missense Mutation (SNP) | VAF 35/38 reads (92%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.634); catalogued as COSV60182160; called by muse, mutect2, varscan2
- RPTN | c.1609C>A p.Q537K | Missense Mutation (SNP) | VAF 259/750 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); catalogued as COSV60169610; called by muse, mutect2, varscan2
- RYR3 | c.9496G>A p.E3166K (on ENST00000389232; = p.E3167K on NM_001036.6) | Missense Mutation (SNP) | VAF 58/146 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0.335); catalogued as COSV66811367; called by muse, mutect2, varscan2
- SDHA | c.202G>T p.G68C | Missense Mutation (SNP) | VAF 48/127 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV53767902; called by muse, mutect2, varscan2
- SDHA | c.203G>T p.G68V | Missense Mutation (SNP) | VAF 48/127 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV53774615; called by muse, mutect2, varscan2
- SERPINB6 | c.853G>A p.E285K (on ENST00000612421 / NM_001271823.2; = p.E266K on NM_004568.6) | Missense Mutation (SNP) | VAF 58/188 reads (31%) | SIFT tolerated (0.32); PolyPhen benign (0.074); catalogued as rs199796495, COSV59567888; called by muse, mutect2, varscan2
- SIGLEC8 | c.1172C>T p.S391L | Missense Mutation (SNP) | VAF 21/97 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.184); catalogued as rs1416661862, COSV58471975; called by muse, mutect2, varscan2
- SLC14A1 | c.994G>C p.E332Q | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.001); catalogued as COSV58934833; called by muse, mutect2, varscan2
- SLC22A7 | c.391G>C p.E131Q | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.361); catalogued as COSV65356937; called by muse, mutect2, varscan2
- SLC30A2 | c.233C>G p.S78C | Missense Mutation (SNP) | VAF 30/110 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.033); catalogued as rs757131894, COSV65333536; called by muse, mutect2, varscan2
- SLC39A5 | c.932G>C p.R311P | Missense Mutation (SNP) | VAF 41/133 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.539); catalogued as COSV57194035; called by muse, mutect2, varscan2
- SLC8A2 | c.268G>A p.A90T | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs767770228, COSV52643545; called by muse, mutect2, varscan2
- SLC9A5 | c.1341G>C p.L447F | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV55363305; called by muse, mutect2, varscan2
- SLX4IP | c.863G>A p.R288Q | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as rs200004663, COSV57952594; called by muse, mutect2, varscan2
- SMARCC2 | c.2304G>C p.E768D | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV57226095; called by muse, mutect2, varscan2
- SMG1 | c.9143C>T p.S3048L | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.108); catalogued as COSV67175267; called by muse, mutect2, varscan2
- SMG8 | c.1369G>C p.E457Q | Missense Mutation (SNP) | VAF 45/111 reads (41%) | SIFT tolerated (0.66); PolyPhen benign (0.026); catalogued as COSV56287518; called by muse, mutect2, varscan2
- SNCAIP | c.592G>A p.E198K | Missense Mutation (SNP) | VAF 35/99 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.874); catalogued as COSV54423695; called by muse, mutect2, varscan2
- SOCS6 | c.1079C>T p.S360L | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.084); catalogued as rs779619824, COSV67546124; called by muse, mutect2, varscan2
- SPOP | c.628G>C p.E210Q | Missense Mutation (SNP) | VAF 83/179 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.389); catalogued as COSV61656187; called by muse, mutect2, varscan2
- SRR | c.334G>C p.D112H | Missense Mutation (SNP) | VAF 83/118 reads (70%) | SIFT tolerated (0.06); PolyPhen benign (0.325); catalogued as COSV56787553; called by muse, mutect2, varscan2
- STARD4 | c.532C>A p.R178S | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT tolerated (0.73); PolyPhen possibly damaging (0.763); catalogued as COSV56969352; called by muse, mutect2, varscan2
- STX11 | c.292G>A p.E98K | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.49); catalogued as rs1449481982, COSV62450809; called by muse, mutect2, varscan2
- SVIL | c.4352G>C p.R1451T (on ENST00000355867 / NM_021738.3; = p.R1025T on NM_003174.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as COSV63449407; called by muse, mutect2, varscan2
- SYNE2 | c.1921G>C p.D641H | Missense Mutation (SNP) | VAF 31/74 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV59974101; called by muse, mutect2, varscan2
- SYTL2 | c.1320C>G p.I440M | Missense Mutation (SNP) | VAF 30/97 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.071); catalogued as COSV60359867; called by muse, mutect2, varscan2
- SYTL2 | c.974C>G p.S325C | Missense Mutation (SNP) | VAF 34/110 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.728); catalogued as COSV60355683, COSV60364905; called by muse, mutect2, varscan2
- TACC2 | c.5738C>T p.S1913L | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs377123555; called by muse, mutect2
- TANC2 | c.5937C>G p.I1979M | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.798); catalogued as COSV67343010; called by muse, mutect2, varscan2
- TJP1 | c.2240C>T p.S747F | Missense Mutation (SNP) | VAF 44/117 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62047420; called by muse, mutect2, varscan2
- TMC4 | c.1472A>T p.D491V (on ENST00000617472 / NM_001145303.3; = p.D485V on NM_144686.4) | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55829212; called by muse, mutect2, varscan2
- TNKS1BP1 | c.3979G>C p.D1327H | Missense Mutation (SNP) | VAF 59/168 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.087); catalogued as COSV64103053; called by muse, mutect2, varscan2
- TRDMT1 | c.121G>A p.E41K | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT tolerated (0.29); PolyPhen benign (0.013); catalogued as COSV58321187; called by muse, mutect2, varscan2
- TRIM31 | c.88G>A p.D30N | Missense Mutation (SNP) | VAF 28/86 reads (33%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.88); catalogued as COSV65060389; called by muse, mutect2, varscan2
- TRIM32 | c.1853G>A p.C618Y | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.979); catalogued as rs777285202, COSV57824575; called by muse, mutect2, varscan2
- TRMT2A | c.1468G>A p.E490K | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as rs200994055; called by muse, mutect2, varscan2
- TRO | c.2486C>G p.S829C | Missense Mutation (SNP) | VAF 41/46 reads (89%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV51509284; called by muse, mutect2, varscan2
- TTC3 | c.1636C>G p.L546V | Missense Mutation (SNP) | VAF 34/103 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV61297481; called by muse, mutect2, varscan2
- TTN | c.56497C>T p.P18833S (on ENST00000591111; = p.P11409S on NM_003319.4) | Missense Mutation (SNP) | VAF 28/92 reads (30%) | PolyPhen probably damaging (0.998); catalogued as COSV60376343; called by muse, mutect2, varscan2
- TUT7 | c.2441G>C p.G814A | Missense Mutation (SNP) | VAF 30/93 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as COSV52899663; called by muse, mutect2, varscan2
- TYW3 | c.283G>A p.D95N | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.24); PolyPhen benign (0.062); catalogued as rs758441583, COSV63803441; called by muse, mutect2, varscan2
- UBA1 | c.1288G>A p.E430K | Missense Mutation (SNP) | VAF 42/47 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV60116104; called by muse, mutect2, varscan2
- UBN1 | c.1990G>A p.D664N | Missense Mutation (SNP) | VAF 41/145 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52174011; called by muse, mutect2, varscan2
- UMODL1 | c.2695G>A p.D899N (on ENST00000408910 / NM_001004416.2; = p.D1027N on NM_173568.3) | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as rs1446268427, COSV68569683; called by muse, mutect2, varscan2
- UNC5A | c.2200G>C p.E734Q | Missense Mutation (SNP) | VAF 29/94 reads (31%) | SIFT tolerated (0.29); PolyPhen benign (0.171); catalogued as COSV52845753; called by muse, mutect2, varscan2
- USP29 | c.2035G>A p.E679K | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0.197); catalogued as rs143453181, COSV99518715; called by muse, mutect2, varscan2
- USP32 | c.2188G>C p.E730Q | Missense Mutation (SNP) | VAF 46/199 reads (23%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.658); catalogued as COSV56279018; called by muse, mutect2, varscan2
- USP32 | c.2131G>C p.E711Q | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV100341096, COSV56267657, COSV56279028; called by muse, varscan2
- VARS2 | c.2324C>A p.S775Y | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV58915521; called by muse, mutect2, varscan2
- WDR41 | c.1121G>T p.R374I | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.499); catalogued as COSV57001165; called by muse, mutect2, varscan2
- ZFHX3 | c.5518C>G p.Q1840E | Missense Mutation (SNP) | VAF 30/67 reads (45%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.467); catalogued as COSV51740253; called by muse, mutect2, varscan2
- ZMYM5 | c.950C>T p.S317F | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.506); catalogued as COSV61990535; called by muse, mutect2, varscan2
- ZNF425 | c.1525C>G p.Q509E | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (0.24); PolyPhen benign (0.046); catalogued as COSV65201715; called by muse, mutect2, varscan2
- ZNF430 | c.1194G>C p.E398D | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.781); catalogued as COSV55113291; called by muse, mutect2, varscan2
- ZNF680 | c.265C>G p.H89D | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.444); catalogued as COSV59018850; called by muse, mutect2, varscan2
- ZNF804A | c.2890T>C p.S964P | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV56475732; called by muse, mutect2, varscan2
- ZNF83 | c.1255C>T p.H419Y | Missense Mutation (SNP) | VAF 29/134 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs563662573, COSV56532958; called by muse, mutect2, varscan2
- ZSCAN1 | c.223G>T p.E75* | Nonsense Mutation (SNP) | VAF 6/27 reads (22%) | catalogued as COSV56607248; called by muse, mutect2, varscan2
- AFDN | c.2559dup p.T854Yfs*4 | Frame Shift Ins (INS) | VAF 11/56 reads (20%) | called by mutect2, pindel, varscan2
- ARID2 | c.1099_1103dup p.F369Ifs*4 | Frame Shift Ins (INS) | VAF 9/56 reads (16%) | called by mutect2, pindel, varscan2
- CHD4 | c.1681_1684del p.Y561Sfs*43 (on ENST00000357008 / NM_001363606.2; = p.Y574Sfs*43 on NM_001273.5) | Frame Shift Del (DEL) | VAF 35/131 reads (27%) | called by mutect2, pindel, varscan2
- FAT1 | c.4341dup p.D1448Rfs*4 | Frame Shift Ins (INS) | VAF 7/30 reads (23%) | called by mutect2, pindel
- FOXQ1 | c.598dup p.S200Kfs*249 | Frame Shift Ins (INS) | VAF 20/34 reads (59%) | called by mutect2, pindel, varscan2
- GDF2 | c.988A>T p.T330S | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT tolerated (0.31); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- HECTD1 | c.2728G>C p.E910Q | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- KRT19 | c.1087dup p.Y363Lfs*75 | Frame Shift Ins (INS) | VAF 11/72 reads (15%) | called by mutect2, pindel, varscan2
- MPV17L | c.334G>C p.D112H | Missense Mutation (SNP) | VAF 2/11 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); called by muse, mutect2
- NRXN1 | c.2626G>T p.G876* | Nonsense Mutation (SNP) | VAF 9/36 reads (25%) | called by muse, mutect2, varscan2
- SHC4 | c.1072G>T p.E358* | Nonsense Mutation (SNP) | VAF 28/85 reads (33%) | called by muse, mutect2, varscan2
- SOX2 | c.84_111del p.A29Rfs*8 | Frame Shift Del (DEL) | VAF 8/30 reads (27%) | called by mutect2, pindel
- SRCIN1 | c.3370G>C p.E1124Q (on ENST00000621492; = p.E1090Q on NM_025248.3) | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT tolerated (0.87); PolyPhen benign (0.244); called by muse, mutect2, varscan2
- TBK1 | c.1357G>A p.D453N | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.15); PolyPhen benign (0.398); called by muse, mutect2, varscan2
- TMEM120A | c.691A>C p.S231R | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TMEM120B | c.548C>G p.S183* | Nonsense Mutation (SNP) | VAF 15/47 reads (32%) | called by muse, mutect2, varscan2
- TMEM165 | c.689T>A p.L230* | Nonsense Mutation (SNP) | VAF 3/34 reads (9%) | called by muse, mutect2
- VIT | c.490G>T p.E164* | Nonsense Mutation (SNP) | VAF 14/27 reads (52%) | called by muse, mutect2, varscan2
- AGRN | c.2112C>G p.V704= | Silent (SNP) | VAF 26/62 reads (42%) | catalogued as COSV65069015, COSV65072889; called by muse, mutect2, varscan2
- ANK3 | c.10158G>A p.G3386= | Silent (SNP) | VAF 37/105 reads (35%) | catalogued as COSV55086869; called by muse, mutect2, varscan2
- ATP2A3 | c.282C>T p.I94= | Silent (SNP) | VAF 10/14 reads (71%) | catalogued as COSV59236243; called by muse, mutect2, varscan2
- BRD1 | c.2175C>T p.L725= | Silent (SNP) | VAF 18/51 reads (35%) | catalogued as rs557124526, COSV53462591; called by muse, mutect2, varscan2
- CCDC121 | c.165G>A p.E55= | Silent (SNP) | VAF 65/176 reads (37%) | catalogued as COSV53118197; called by muse, mutect2, varscan2
- CSRP3 | c.183C>T p.C61= | Silent (SNP) | VAF 25/77 reads (32%) | catalogued as rs34075817; called by muse, mutect2, varscan2
- DCHS1 | c.9717C>T p.I3239= | Silent (SNP) | VAF 8/14 reads (57%) | catalogued as COSV55000368; called by muse, mutect2, varscan2
- DYNC2I2 | c.1230C>T p.S410= | Silent (SNP) | VAF 16/50 reads (32%) | catalogued as rs146817584; called by muse, mutect2, varscan2
- EHMT1 | c.2634C>T p.I878= | Silent (SNP) | VAF 4/25 reads (16%) | catalogued as rs770369621, COSV71778881; called by muse, mutect2, varscan2
- ETFB | c.192C>T p.V64= | Silent (SNP) | VAF 11/39 reads (28%) | catalogued as COSV58538089; called by muse, mutect2, varscan2
- FAAP24 | c.444G>A p.K148= | Silent (SNP) | VAF 31/100 reads (31%) | catalogued as rs1301945133, COSV54285901; called by muse, mutect2, varscan2
- FAM126B | c.516C>T p.F172= | Silent (SNP) | VAF 15/45 reads (33%) | catalogued as COSV53775693; called by muse, mutect2, varscan2
- FBXL2 | c.663C>T p.I221= | Silent (SNP) | VAF 53/92 reads (58%) | catalogued as COSV52143610; called by muse, mutect2, varscan2
- FCRLB | c.1101G>A p.L367= | Silent (SNP) | VAF 18/50 reads (36%) | called by muse, mutect2, varscan2
- FOSB | c.942C>T p.F314= | Silent (SNP) | VAF 23/96 reads (24%) | catalogued as rs773011979, COSV62278645, COSV62278726; called by muse, mutect2, varscan2
- GABRG2 | c.624C>T p.F208= | Silent (SNP) | VAF 12/24 reads (50%) | catalogued as COSV62723397; called by muse, mutect2
- GRM7 | c.1512C>G p.L504= | Silent (SNP) | VAF 20/99 reads (20%) | catalogued as COSV63133825, COSV63177193; called by muse, mutect2, varscan2
- KARS1 | c.1494G>A p.A498= | Silent (SNP) | VAF 38/109 reads (35%) | catalogued as rs374568114; called by muse, mutect2, varscan2
- KCNK10 | c.654G>A p.E218= | Silent (SNP) | VAF 21/63 reads (33%) | catalogued as COSV56646643; called by muse, mutect2, varscan2
- KCTD19 | c.2613C>T p.I871= | Silent (SNP) | VAF 5/17 reads (29%) | catalogued as rs756599781, COSV58575856; called by muse, mutect2, varscan2
- LRRK2 | c.3808C>T p.L1270= | Silent (SNP) | VAF 21/57 reads (37%) | catalogued as rs201775131, COSV54174883; called by muse, mutect2, varscan2
- MAST4 | c.5274C>G p.L1758= (on ENST00000403625 / NM_001164664.2; = p.L1569= on NM_015183.3) | Silent (SNP) | VAF 16/52 reads (31%) | catalogued as COSV55145957; called by muse, mutect2, varscan2
- MEN1 | c.684G>A p.L228= | Silent (SNP) | VAF 26/49 reads (53%) | catalogued as COSV53649726; called by muse, mutect2, varscan2
- MLNR | c.1152G>A p.R384= | Silent (SNP) | VAF 18/57 reads (32%) | catalogued as COSV54534806; called by muse, mutect2, varscan2
- MUC6 | c.2493C>T p.F831= | Silent (SNP) | VAF 6/17 reads (35%) | catalogued as rs1426016369, COSV70137472, COSV70151511; called by muse, mutect2, varscan2
- NOG | c.291C>A p.G97= | Silent (SNP) | VAF 9/16 reads (56%) | catalogued as COSV60447818; called by muse, mutect2, varscan2
- NR4A3 | c.138G>A p.E46= | Silent (SNP) | VAF 21/61 reads (34%) | catalogued as COSV58249028; called by muse, mutect2, varscan2
- OCM2 | c.21C>T p.L7= | Silent (SNP) | VAF 9/36 reads (25%) | catalogued as COSV57535990; called by muse, mutect2, varscan2
- OR2M7 | c.627C>T p.F209= | Silent (SNP) | VAF 88/297 reads (30%) | catalogued as COSV58737739; called by muse, mutect2, varscan2
- OR6N2 | c.147C>T p.I49= | Silent (SNP) | VAF 26/105 reads (25%) | catalogued as COSV59413101; called by muse, mutect2, varscan2
- OR8D2 | c.831C>T p.F277= | Silent (SNP) | VAF 35/91 reads (38%) | catalogued as COSV62489224; called by muse, mutect2, varscan2
- RBL2 | c.3419G>A p.*1140= | Silent (SNP) | VAF 17/54 reads (31%) | catalogued as rs1360045137; called by muse, mutect2, varscan2
- RPL6 | c.660G>A p.K220= | Silent (SNP) | VAF 16/51 reads (31%) | catalogued as COSV52518325; called by muse, mutect2, varscan2
- RSPH14 | c.531C>A p.L177= | Silent (SNP) | VAF 7/23 reads (30%) | catalogued as COSV53272878; called by muse, mutect2, varscan2
- SERPINB8 | c.222C>T p.L74= | Silent (SNP) | VAF 41/116 reads (35%) | catalogued as COSV54640885; called by muse, mutect2, varscan2
- SLC38A6 | c.996G>A p.V332= | Silent (SNP) | VAF 12/37 reads (32%) | catalogued as COSV50787188; called by muse, mutect2, varscan2
- SMPD4 | c.2115C>T p.L705= (on ENST00000409031 / NM_017951.4; = p.L676= on NM_017751.4) | Silent (SNP) | VAF 13/42 reads (31%) | catalogued as rs1174740350, COSV60083453; called by muse, mutect2, varscan2
- SPIRE2 | c.1608G>C p.L536= | Silent (SNP) | VAF 12/36 reads (33%) | catalogued as COSV65558059; called by muse, mutect2, varscan2
- SUPT5H | c.792C>G p.L264= | Silent (SNP) | VAF 22/95 reads (23%) | catalogued as COSV63242703; called by muse, mutect2, varscan2
- TMEM231 | c.528G>C p.L176= (on ENST00000258173 / NM_001077418.3; = p.L205= on NM_001077416.2) | Silent (SNP) | VAF 43/104 reads (41%) | catalogued as COSV50740024; called by muse, mutect2, varscan2
- TMEM234 | c.75G>A p.L25= | Silent (SNP) | VAF 12/38 reads (32%) | catalogued as COSV59085947; called by muse, mutect2, varscan2
- TRIM28 | c.517C>T p.L173= | Silent (SNP) | VAF 14/53 reads (26%) | catalogued as COSV53402094; called by muse, mutect2, varscan2
- TRIM71 | c.2535C>T p.S845= | Silent (SNP) | VAF 31/160 reads (19%) | catalogued as rs1482040694, COSV67470256; called by muse, mutect2, varscan2
- TRIO | c.2073G>A p.Q691= | Silent (SNP) | VAF 9/27 reads (33%) | catalogued as rs750259424, COSV60099273; called by muse, mutect2, varscan2
- ZNF425 | c.444C>G p.L148= | Silent (SNP) | VAF 25/77 reads (32%) | catalogued as COSV65203017; called by muse, mutect2, varscan2
- CCNQP1 | n.421C>T | RNA (SNP) | VAF 10/46 reads (22%) | catalogued as rs543927348; called by muse, mutect2, varscan2
- MIR646 | n.11C>A | RNA (SNP) | VAF 10/34 reads (29%) | called by muse, mutect2, varscan2
- NMT1 | c.-1G>C | 5'UTR (SNP) | VAF 5/31 reads (16%) | catalogued as COSV99364551; called by muse, mutect2, varscan2
- SALL2 | c.*498G>A | 3'UTR (SNP) | VAF 4/15 reads (27%) | catalogued as COSV100444088; called by muse, mutect2
- ZAN | c.7787+25G>A | Intron (SNP) | VAF 14/27 reads (52%) | catalogued as rs377332360; called by muse, mutect2, varscan2
- ZNF665 | c.-53-9189C>T | Intron (SNP) | VAF 28/135 reads (21%) | catalogued as COSV67213475, COSV67216594, COSV67218127; called by muse, mutect2, varscan2
